Somatic mutation profile of tumor specimen TCGA-DX-A3M2-01A (aliquot TCGA-DX-A3M2-01A-21D-A228-09) from TCGA case TCGA-DX-A3M2, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 59.4 years (21,689 days).
Specimen TCGA-DX-A3M2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15298bf7-3dd9-4f86-a516-ff585f5a6528.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3M2-10A (Blood Derived Normal), aliquot TCGA-DX-A3M2-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae5a6849-118e-4ffb-8d40-fa946afcec22

The open-access MAF lists 89 somatic variants for this specimen: 64 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 23, Nonsense Mutation 3, RNA 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as rs122456134, CM980292, COSV100544544; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 55/118 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.5428G>A p.A1810T (on ENST00000614293; = p.A1780T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as rs987447708, COSV99687480; called by muse, mutect2, varscan2
- ACACB | c.6651A>T p.E2217D | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100622565; called by muse, mutect2
- ASPG | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs767557661, COSV71934120; called by muse, mutect2
- ATRX | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as COSV64873412; called by muse, mutect2, varscan2
- BCAR3 | c.2063G>T p.S688I | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.499); catalogued as COSV53078841; called by muse, mutect2
- BMP6 | c.901T>A p.S301T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as COSV99306573; called by muse, mutect2, varscan2
- CACNG6 | c.772C>T p.R258W (on ENST00000252729 / NM_145814.1; = p.R187W on NM_031897.2) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.333); catalogued as rs1219732417, COSV53167342, COSV99403343; called by muse, mutect2
- CFAP100 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs377186686, COSV100729015; called by muse, mutect2, varscan2
- CIT | c.3145G>A p.V1049I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs200184645, COSV55887119; called by muse, mutect2, varscan2
- COP1 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV58171581; called by muse, mutect2
- DNAJC14 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs139009579; called by mutect2, varscan2
- DSCAM | c.5987G>A p.R1996Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs759558023, COSV68026253; called by muse, mutect2
- ELOVL2 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as rs1161557499, COSV61154120; called by muse, mutect2, varscan2
- EPYC | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99664546; called by muse, mutect2, varscan2
- ERAP2 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV101163566; called by mutect2, varscan2
- FAM135B | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771996168, COSV50523016; called by muse, mutect2, varscan2
- FBXO41 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as rs375457673; called by muse, mutect2
- FCHO1 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs970252335, COSV99405919; called by muse, mutect2, varscan2
- FPGT | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.23); catalogued as COSV100907094, COSV100907213; called by muse, mutect2, varscan2
- GPR151 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs748971610, COSV57042549; called by muse, mutect2, varscan2
- GPT2 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs772285948, COSV60839199; called by muse, mutect2, varscan2
- HDAC6 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61929979; called by muse, mutect2, varscan2
- HPN | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52883848; called by muse, mutect2, varscan2
- ITGB2 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100185712; called by muse, mutect2, varscan2
- KDM5C | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV62891247; called by muse, mutect2, varscan2
- LRRN3 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV100068988; called by muse, mutect2
- MYO15A | c.1072C>A p.L358I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.127); catalogued as COSV99231744; called by muse, mutect2, varscan2
- NSUN6 | c.859A>T p.I287F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101045469; called by muse, mutect2
- OBSCN | c.4669G>A p.E1557K | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs373860140; called by muse, mutect2, varscan2
- OR8H2 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100542216; called by muse, mutect2, varscan2
- PCDH1 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as rs1235954983, COSV99745773; called by muse, mutect2, varscan2
- PEG3 | c.760C>A p.L254M | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99687991; called by muse, mutect2
- PIWIL2 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.861); catalogued as rs754274857, COSV63250286; called by muse, mutect2
- RASAL2 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.728); catalogued as rs368617203; called by muse, mutect2, varscan2
- RSAD1 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375677855; called by muse, mutect2, varscan2
- SCAF1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs759490334, COSV100862083, COSV100862214; called by muse, mutect2, varscan2
- SCN3A | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.988); catalogued as rs771117930, COSV51807783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA6D | c.1341G>T p.M447I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100316665, COSV60382048; called by muse, mutect2, varscan2
- SIGLEC1 | c.4228C>T p.R1410W | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs200539652, COSV99163562; called by muse, mutect2, varscan2
- SLC16A5 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753744110, COSV100317013; called by muse, mutect2, varscan2
- SLC32A1 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.274); catalogued as COSV99461966; called by muse, mutect2
- SLC39A5 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs555836955, COSV57190851; called by muse, mutect2
- SLC6A17 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446781497, COSV100521161; called by muse, mutect2, varscan2
- SLC7A9 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs769448665, CM010443, COSV50082863; called by muse, mutect2, varscan2
- SPATA31A1 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1263699676; called by muse, mutect2, varscan2
- SPEF2 | c.4597G>A p.V1533M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200747497, COSV100288610; called by muse, mutect2, varscan2
- SPHK2 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as rs758872660, COSV99709238; called by muse, mutect2, varscan2
- SPINK5 | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757605120, COSV99806334; called by muse, mutect2, varscan2
- SPRED1 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs769630742, COSV54439518; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTBN4 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58959511; called by muse, mutect2, varscan2
- TAF6L | c.1026T>A p.D342E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); catalogued as COSV99585036; called by muse, mutect2, varscan2
- TAPBPL | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56947773, COSV99869061; called by muse, mutect2, varscan2
- TAS1R1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs779636670, COSV100039555; called by muse, mutect2, varscan2
- TBC1D12 | c.1891A>T p.M631L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV99831276; called by muse, mutect2
- TMEM52B | c.196C>G p.R66G (on ENST00000381923 / NM_001079815.1; = p.R46G on NM_153022.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100046370, COSV53729331; called by muse, mutect2, varscan2
- TUB | c.1399G>A p.V467M (on ENST00000299506 / NM_177972.3; = p.V522M on NM_003320.4) | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs527582687, COSV55110473; called by muse, mutect2
- ZC3H18 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); catalogued as COSV99963942; called by muse, mutect2
- ZNF85 | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.313); catalogued as rs1269597523, COSV60215131; called by muse, mutect2, varscan2
- ZSCAN1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs779306454, COSV99991467; called by muse, mutect2, varscan2
- ALPK2 | c.4034del p.P1345Lfs*2 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- CRABP2 | c.151T>G p.F51V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2
- LPCAT4 | c.1414_1418del p.F472Pfs*3 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- ABT1 | c.519G>A p.A173= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs782401511, COSV99223163; called by muse, mutect2, varscan2
- AQP6 | c.369G>A p.P123= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as rs150838227, COSV100210122; called by muse, mutect2, varscan2
- BCL9 | c.4098C>T p.A1366= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs782624393, COSV52345731; called by muse, mutect2
- CACNA1E | c.4599C>A p.G1533= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as rs746008322, COSV100701599; called by muse, mutect2, varscan2
- CASQ2 | c.861C>A p.I287= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs143718767; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CCDC63 | c.1023G>A p.T341= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs549200490, COSV57527025; called by muse, mutect2, varscan2
- CD209 | c.1068C>T p.C356= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs749655694, COSV52652610; called by muse, mutect2, varscan2
- EIF2AK4 | c.4224T>C p.S1408= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV99774341; called by muse, mutect2
- FLT4 | c.3411G>A p.P1137= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as rs1196765706, COSV99986348; called by muse, mutect2, varscan2
- FTCD | c.624C>T p.R208= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs775966116, COSV52425740; called by muse, mutect2, varscan2
- GLB1 | c.1470C>T p.N490= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs748007307, COSV56565600; called by muse, mutect2, varscan2
- HTT | c.6810G>A p.P2270= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs370817761; called by muse, mutect2, varscan2
- JAKMIP1 | c.1125G>A p.A375= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs150623866; called by muse, mutect2, varscan2
- KRT35 | c.585G>A p.L195= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV55843706; called by muse, varscan2
- OR7G2 | c.342G>A p.T114= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs768345758, COSV59688799; called by muse, mutect2, varscan2
- OR8H1 | c.747C>A p.I249= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100476930, COSV57295661; called by muse, mutect2, varscan2
- PRKCG | c.1380C>T p.Y460= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs762961166, COSV54723632, COSV54727512; called by muse, mutect2, varscan2
- QTRT2 | c.1161C>T p.Y387= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as COSV99846845; called by muse, mutect2
- RBBP8NL | c.1713C>T p.D571= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as rs568878182, COSV53349199, COSV53350150; called by muse, mutect2, varscan2
- RP1 | c.597C>T p.Y199= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs748104371, CM1312795, COSV55117925; called by muse, mutect2, varscan2
- SOHLH1 | c.864G>A p.A288= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs764239665, COSV53681104; called by muse, mutect2
- TECTA | c.1122C>T p.A374= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs560630226, COSV99879123; called by muse, mutect2, varscan2
- TLN2 | c.6495C>T p.D2165= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV60892182; called by muse, mutect2, varscan2
- KRT18P55 | n.992G>A | RNA (SNP) | VAF 13/47 reads (28%) | catalogued as rs973952135; called by muse, mutect2, varscan2
- MIR202 | n.2G>A | RNA (SNP) | VAF 23/95 reads (24%) | catalogued as rs1185844496; called by muse, mutect2, varscan2
